Gene-level copy-number profile of tumor specimen TCGA-98-A53J-01A from TCGA case TCGA-98-A53J, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 78.0 years (28,485 days).
Specimen TCGA-98-A53J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.658798bd-4410-4f62-8a5a-d187fc676fe5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-98-A53J-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d801b6ae-eede-45a2-b0b6-ecff40172832

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 1: 29,946; copy number 2: 23,813; copy number 3: 4,171; copy number 4: 1,103; copy number 5: 728; copy number 8: 52.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-98-A53J-01A-11D-A26L-01): tumor purity 0.4, ploidy 3.42, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 6,054 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:67,522,299–68,943,452, 26 genes, copy number 3 (within-gene range 2–3): LINC01702, RNU6-1031P, AL590559.1, RN7SL392P, HNRNPCP9, GADD45A, GNG12, RNU7-80P, GNG12-AS1, AL157407.1, DIRAS3, ARL5AP3, WLS, CTBP2P8, MIR1262, RPS7P4, COX6B1P7, ELOCP18, AL139413.1, RPE65, DEPDC1, AL138789.1, DEPDC1-AS1, TXNP2, AL035412.1, AL033530.1.
- chr1:72,636,547–72,899,240, 1 gene, copy number 3 (within-gene range 2–3): AL583808.1.
- chr1:72,765,031–73,915,340, 10 genes, copy number 3: LINC02796, LINC02797, AL732618.1, KRT8P21, RN7SKP19, LINC01360, LINC02238, RNA5SP50, AL591463.1, RNU4ATAC8P.
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 3 (broad region; genes not listed).
- chr3:79,957,566–82,808,021, 21 genes, copy number 3 (within-gene range 1–3): HMGB1P38, OSBPL9P1, HNRNPA3P8, AC108740.1, AC108690.1, AC068756.1, LINC02050, LINC02027, AC099542.2, AC099542.1, AC107302.2, AC107302.1, GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008, RPL7AP23, CYP51A1P1.
- chr3:91,356,755–198,222,513, 1,802 genes, copy number 4–5 (broad region; genes not listed).
- chr7:70,972–64,150,721, 1,153 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr19:30,665,274–39,400,641, 356 genes, copy number 3 (broad region; genes not listed).
- chr19:57,769,655–58,605,223, 81 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 27,525. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
